Gene-level copy-number profile of tumor specimen TCGA-D8-A1XA-01A from TCGA case TCGA-D8-A1XA, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.0 years (23,387 days).
Specimen TCGA-D8-A1XA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.a6a18a90-cdd5-4a5f-a8a2-6480bc1742c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1XA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f45d2f7-ea1e-47c6-b1b4-8cab455c65eb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 22,107; copy number 3: 4,189; copy number 4: 30,323; copy number 6: 2,488; copy number 7: 703; copy number 9: 3; copy number 11: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1XA-01A-11D-A14F-01): tumor purity 0.84, ploidy 1.66, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:44,495,099–44,828,592, 7 genes, copy number 11: LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2.
- chr5:172,042,079–172,283,764, 3 genes, copy number 9 (within-gene range 6–9): STK10, EFCAB9, UBTD2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
